Somatic mutation profile of tumor specimen TARGET-10-PARBWN-09A (aliquot TARGET-10-PARBWN-09A-01D) from TARGET case TARGET-10-PARBWN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,260 days).
Specimen TARGET-10-PARBWN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0be4fdd-599e-472d-9c4e-c52047f84731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBWN-10A (Blood Derived Normal), aliquot TARGET-10-PARBWN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02d80261-a528-458f-a778-73abd345db3a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57494362; called by muse, mutect2, varscan2
- CCAR2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV51514935; called by muse, mutect2, varscan2
- SNX4 | c.647C>G p.P216R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CEP55 | c.738A>G p.K246= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV65184955; called by muse, mutect2
- METTL27 | c.150G>A p.A50= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs782124859; called by muse, mutect2
- MUC5AC | c.14628G>A p.E4876= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
